Somatic mutation profile of tumor specimen MP2PRT-PASNUW-TMP1-A (aliquot MP2PRT-PASNUW-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PASNUW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (741 days).
Specimen MP2PRT-PASNUW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0a9723b-d39d-44fa-9576-e37a9fe608ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNUW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNUW-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/031a7fd2-0460-4034-8866-2a362a5e0610

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD300LF | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV56898263; called by muse, mutect2
- ERN2 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 165/406 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs979868350; called by muse, mutect2, varscan2
- FREM2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 274/672 reads (41%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.146); catalogued as rs553605556, COSV99748916; called by muse, mutect2, varscan2
- GATA1 | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 17/699 reads (2%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1557020191, COSV64962478; called by muse, mutect2
- NPR1 | c.591C>G p.F197L | Missense Mutation (SNP) | VAF 38/407 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV64142123; called by muse, mutect2
- POSTN | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs758714986, COSV65712304; called by muse, mutect2, varscan2
- PTPRN2 | c.2238G>C p.E746D | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV67054921; called by muse, mutect2, varscan2
- SLC6A14 | c.17G>A p.C6Y | Missense Mutation (SNP) | VAF 147/338 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.248); catalogued as rs1556693308; called by muse, mutect2, varscan2
- SPATA31D1 | c.2857C>G p.Q953E | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61199899; called by muse, mutect2
- WDR62 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV54339362, COSV99544346; called by muse, mutect2, varscan2
- ZNF570 | c.155C>G p.S52* | Nonsense Mutation (SNP) | VAF 17/112 reads (15%) | catalogued as COSV57578329; called by muse, mutect2, varscan2
- AP4E1 | c.1843G>C p.D615H | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- IGHV1-69 | chr14:106714671 del TTCACACTGTGTCTCTCGCACAGTAATACACGGCCG | Missense Mutation (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- KRI1 | c.1881G>C p.E627D | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.073); called by muse, mutect2
- LRP1 | c.5851C>T p.R1951W | Missense Mutation (SNP) | VAF 183/395 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RHOV | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SNTG1 | c.1526C>A p.T509N | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF174 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 13/386 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.358); called by muse, mutect2
- ZNF404 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 17/289 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.409); called by muse, mutect2
- CFAP58 | c.2595C>G p.L865= | Silent (SNP) | VAF 28/281 reads (10%) | catalogued as COSV63836392; called by muse, mutect2
- POLD1 | c.939C>G p.L313= | Silent (SNP) | VAF 12/427 reads (3%) | called by muse, mutect2
- RGS9 | c.72G>A p.V24= | Silent (SNP) | VAF 26/275 reads (9%) | called by muse, mutect2, varscan2
- SF3B3 | c.3465C>T p.L1155= | Silent (SNP) | VAF 12/400 reads (3%) | catalogued as COSV100209518; called by muse, mutect2
- SLC36A2 | c.408C>T p.N136= | Silent (SNP) | VAF 101/235 reads (43%) | catalogued as rs757471205, COSV58862182; called by muse, mutect2, varscan2
- ZNF550 | c.337C>T p.L113= | Silent (SNP) | VAF 34/374 reads (9%) | called by muse, mutect2
- IFI27L1 | c.-98+6851G>C | Intron (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
